Gene-level copy-number profile of tumor specimen C3N-04152-01 from CPTAC case C3N-04152, project CPTAC-3 (Oropharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.9 years (19,705 days).
Specimen C3N-04152-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a3ff5421-c2cb-451c-a34d-f9536c62423b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04152-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,853 have no estimate.
https://portal.gdc.cancer.gov/files/5fb47d82-d43a-4625-88b9-4d3135e6bdfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 366; copy number 1: 16,063; copy number 2: 36,381; copy number 3: 3,998; copy number 4: 365; copy number 5: 382; copy number 6: 892; copy number 7: 97; copy number 8: 24; copy number 10: 5; copy number 11: 17; copy number 12: 30; copy number 13: 67; copy number 16: 32; copy number 17: 4; copy number 20: 34; copy number 29: 13.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,341,426–12,388,296, 5 genes: DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,597 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:149,369,022–198,123,232, 857 genes, copy number 5–7 (broad region; genes not listed).
- chr4:88,709,298–89,954,629, 16 genes, copy number 5: FAM13A-AS1, AC108065.2, AC108065.1, FAM13A, TIGD2, AC104785.1, RNU6-907P, GPRIN3, AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1.
- chr8:31,639,222–43,674,591, 230 genes, copy number 5–7 (broad region; genes not listed).
- chr11:68,612,899–74,171,210, 183 genes, copy number 7–20 (within-gene range 2–20) (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:35,278,633–51,096,061, 222 genes, copy number 5–16 (within-gene range 3–16) (broad region; genes not listed).
- chr18:894,435–5,630,700, 85 genes, copy number 5–29 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
